Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6813, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6813-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]	[REDACTED]	Formatted Path Report
------------	------------	-----------------------

[REDACTED]	[REDACTED]	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Excision of tumor Specimen size: Not specified Tumor site: Rectus abdominus Tumor size: 5 x 5 x 1 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Perirectal tissues Lymph nodes: 12/12 positive for metastasis (Pararectal 12/12) Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	[REDACTED]
------------	------------	---	------------

[page 2 of 2]
Date of Procurement

A large, empty rectangular box with a black border, occupying the majority of the page below the header. It appears to be a placeholder for content or a redacted area.

Source: NCI Genomic Data Commons file 723108ee-db92-4873-8dd2-9f35a301cfec (TCGA-F5-6813.1E211347-B80E-439F-813B-4EC3B89E7D73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).